Somatic mutation profile of tumor specimen 0DR1Z7 from CCDI case PBCFAT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.3 years (1,189 days).
Specimen 0DR1Z7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef54ccdf-5ead-43bb-845b-4ef01643cf71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR1YM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c93b016c-329a-4655-84c9-821c9477cb5e

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, 3'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAT2 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 261/829 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.358); catalogued as rs959711687, COSV99395589; called by muse, mutect2, varscan2
- LAMA2 | c.5813C>T p.A1938V | Missense Mutation (SNP) | VAF 1118/1862 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376585927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN5 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 625/1404 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1358755376, COSV53254064; called by muse, mutect2, varscan2
- LRRC7 | c.2858G>A p.R953H (on ENST00000651989 / NM_001370785.2; = p.R920H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 618/1266 reads (49%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.019); catalogued as rs141932871; called by muse, mutect2, varscan2
- NEU4 | c.594C>G p.F198L (on ENST00000391969 / NM_001167602.3; = p.F210L on NM_080741.4) | Missense Mutation (SNP) | VAF 35/619 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as COSV57990043; called by muse, mutect2
- OR2V2 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 112/850 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs370476658; called by muse, mutect2, varscan2
- RGL3 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 206/453 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs779419722, COSV66506061; called by mutect2, varscan2
- TSSC4 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 275/632 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs766495604; called by muse, mutect2, varscan2
- ZFP92 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 381/415 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1556975049; called by muse, mutect2, varscan2
- PSKH1 | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.156); called by muse, mutect2
- RPP25L | c.49C>G p.P17A | Missense Mutation (SNP) | VAF 30/1154 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.278); called by muse, mutect2
- E2F1 | c.7T>C p.L3= | Silent (SNP) | VAF 60/190 reads (32%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1094557 C>A | 3'Flank (SNP) | VAF 288/664 reads (43%) | catalogued as rs530122223; called by mutect2, varscan2
